Somatic mutation profile of tumor specimen TCGA-OR-A5JC-01A (aliquot TCGA-OR-A5JC-01A-11D-A29I-10) from TCGA case TCGA-OR-A5JC, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 38.0 years (13,862 days).
Specimen TCGA-OR-A5JC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d39f862-0782-48ca-9b47-0a85d7cdf9ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5JC-10A (Blood Derived Normal), aliquot TCGA-OR-A5JC-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99cbfb47-8dbd-49e4-9502-c54548883bdc

The open-access MAF lists 26 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 4, Nonsense Mutation 1, Frame Shift Del 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASMTL | c.1252T>C p.Y418H | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV67245170; called by muse, mutect2
- CCDC62 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as rs756743489, COSV99457070; called by muse, mutect2, varscan2
- CFAP52 | c.582C>G p.I194M | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as COSV55347483; called by muse, mutect2, varscan2
- CFAP91 | c.1820G>A p.R607Q | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs556802557, COSV99847345; called by muse, mutect2, varscan2
- CIDEA | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.862); catalogued as rs751972278, COSV57598855; called by muse, mutect2, varscan2
- CSMD1 | c.3274C>T p.R1092C (on ENST00000520002; = p.R1091C on NM_033225.6) | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1480620459, COSV100153077, COSV59278782; called by muse, mutect2, varscan2
- PDK3 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs375475050, COSV64793308; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PHF24 | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761867623; called by muse, mutect2, varscan2
- PLCB4 | c.687C>T p.I229= | Splice Region (SNP) | VAF 12/90 reads (13%) | catalogued as rs1209593673; called by muse, mutect2, varscan2
- ADCY4 | c.1032G>T p.M344I | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL20A1 | c.3448G>A p.G1150S | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- DPPA2 | c.502A>T p.R168* | Nonsense Mutation (SNP) | VAF 33/140 reads (24%) | called by muse, mutect2, varscan2
- EGR3 | c.1003T>A p.C335S | Missense Mutation (SNP) | VAF 108/280 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FATE1 | c.46C>A p.L16M | Missense Mutation (SNP) | VAF 95/269 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FBXO5 | c.379_382del p.L127Ifs*6 | Frame Shift Del (DEL) | VAF 16/129 reads (12%) | called by mutect2, pindel, varscan2
- LGI1 | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PA2G4 | c.652T>A p.F218I | Missense Mutation (SNP) | VAF 10/247 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.842); called by muse, mutect2
- PRKCH | c.766C>G p.P256A | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- PRPF39 | c.70G>C p.V24L | Missense Mutation (SNP) | VAF 46/218 reads (21%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNE1 | c.19405G>T p.D6469Y (on ENST00000367255 / NM_182961.4; = p.D6398Y on NM_033071.3) | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2
- UTRN | c.7207G>C p.E2403Q | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- DCC | c.3234G>A p.P1078= | Silent (SNP) | VAF 38/62 reads (61%) | catalogued as rs746957136, COSV71425277; called by muse, mutect2, varscan2
- FATE1 | c.45C>A p.S15= | Silent (SNP) | VAF 95/267 reads (36%) | called by muse, mutect2, varscan2
- MYOCD | c.264A>G p.A88= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs780955626; called by muse, mutect2, varscan2
- PRKD3 | c.81T>A p.S27= | Silent (SNP) | VAF 10/123 reads (8%) | called by muse, mutect2
- MIR520C | n.24G>C | RNA (SNP) | VAF 26/203 reads (13%) | called by muse, mutect2
